Gene-level copy-number profile of tumor specimen TCGA-29-1774-01A from TCGA case TCGA-29-1774, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 82.1 years (29,991 days).
Specimen TCGA-29-1774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5770446c-7705-4d03-b049-f00601f076f5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1774-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 402 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2bf6e10e-8e28-4d68-a29d-e4956a6793c4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 600; copy number 1: 47; copy number 2: 7,764; copy number 3: 4,140; copy number 4: 27,263; copy number 5: 6,607; copy number 6: 10,364; copy number 7: 1,098; copy number 8: 420; copy number 9: 1,136; copy number 10: 72; copy number 11: 593; copy number 13: 117.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1774-01A-01D-0577-01): tumor purity 0.86, ploidy 2.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr13:31,960,325–31,961,946, 1 gene: AC002525.1.
- chr21:14,108,813–17,894,485, 65 genes (broad region; genes not listed).
- chr22:27,919,376–28,679,865, 12 genes (within-gene range 0–2): TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,918 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:76,772,909–76,773,045, 1 gene, copy number 9: RNA5SP98.
- chr4:53,286–1,745,171, 68 genes, copy number 9 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 11–13 (broad region; genes not listed).
- chr5:60,866,454–62,391,025, 21 genes, copy number 9: ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6, C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157, KIF2A.
- chr5:62,347,284–62,403,939, 1 gene, copy number 9: DIMT1.
- chr14:105,764,503–106,461,055, 117 genes, copy number 9 (broad region; genes not listed).
- chr16:56,730,118–61,055,964, 102 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr16:66,802,875–71,931,199, 244 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr19:53,679,940–54,115,675, 71 genes, copy number 10 (broad region; genes not listed).
- chr19:54,119,511–54,125,343, 1 gene, copy number 10 (within-gene range 7–10): AC245052.4.
- chr20:41,331,123–64,313,132, 582 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
